Surgical pathology report (de-identified scan), TCGA case TCGA-14-2554, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-2554-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

CGA - 14 - 2554

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT PARIETO-OCCIPITAL LESION, BIOPSY, FS1A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
2. BRAIN, RIGHT PARIETO-OCCIPITAL, EXCISION, FS2A:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).
3. BRAIN, RIGHT PARIETO-OCCIPITAL, EXCISION:
- GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

SPECIMEN:

1. Right, brain, parieto-occipital lesion,
2. Right, brain, parieto-occipital lesion,
3. Right, brain, parieto-occipital lesion

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATION: Craniotomy for brain lesion.

Printed by:

Printed on:

[page 2 of 2]
AP Report

* Final Report *

PREOPERATIVE DIAGNOSIS: Right parieto-occipital brain lesion.
POSTOPERATIVE DIAGNOSIS: Right parieto-occipital brain lesion.

GROSS DESCRIPTION:

Received are three specimens. Each is labeled with the patient's name and hospital number.

Specimen #1 is received fresh for intraoperative consultation and is labeled "right parieto-occipital lesion". The specimen consists of multiple pieces of tan tissue which measure 1 x 0.3 x 0.2 cm in aggregate. The specimen is entirely frozen and the remainder of the cryoblock is submitted in cassettes "FS1A" and "1B".

Specimen #2 is received fresh for intraoperative consultation and is labeled "right parieto-occipital lesion". The specimen consists of multiple fragments of tan tissue which measure 5.5 x 2 x 0.5 cm in aggregate. A representative portion is frozen and the remainder of the cryoblock is submitted in cassette "FS2A". The remainder of the tissue is submitted in cassettes "2B" and "2C".

Specimen #3 is received in formalin and is labeled "right parieto-occipital lesion". The specimen consists of multiple fragments of hemorrhagic tan tissue ranging in size from 0.5 x 0.5 x 0.5 to 5 x 3 x 1 cm which measure 6 x 6 x 1 cm in aggregate. Representative sections are taken and submitted in cassettes "3A" through "3D".

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: LEFT PARIETO-OCCIPITAL LESION (FROZEN SECTION, TOUCH PREPARATION):
NECROSIS.

FS2A: RIGHT PARIETO-OCCIPITAL LESION (FROZEN SECTION): GLIOBLASTOMA
MULTIFORME.

TISSUE COMMITTEE CODE:

1

Page 1 (Continued...)

Printed by:
Printed on:

Page 2 of 4
(Continued)

Source: NCI Genomic Data Commons file 51133f6c-dbaa-440d-9512-03310f813a2a (TCGA-14-2554.A55777C9-E369-484C-87FF-F24EC2627A33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).